Somatic mutation profile of tumor specimen ALCH-B258-TTP1-A (aliquot ALCH-B258-TTP1-A-1-0-D-A76I-36) from ALCHEMIST case ALCH-B258, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 53.6 years (19,590 days).
Specimen ALCH-B258-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61a7fdb0-0d51-4428-a3e6-9e08f8062610.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B258-NB1-A (Blood Derived Normal), aliquot ALCH-B258-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e8bcad4-9a11-4c13-82fb-dca9201c66fc

The open-access MAF lists 96 somatic variants for this specimen: 67 protein-altering or splice-affecting, 17 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 17, Intron 5, RNA 4, Nonsense Mutation 4, Splice Region 2, 3'UTR 2, Frame Shift Del 2, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 338/626 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- ADAMTS13 | c.2827C>T p.R943W | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs149265456; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARID2 | c.3382C>T p.Q1128* | Nonsense Mutation (SNP) | VAF 19/191 reads (10%) | catalogued as COSV57598922; called by muse, mutect2, varscan2
- CHRNA9 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.721); catalogued as rs775085099, COSV59573670; called by muse, mutect2
- COG7 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.033); catalogued as rs757810496, COSV56151506; called by muse, mutect2, varscan2
- DTNA | c.703G>T p.E235* | Nonsense Mutation (SNP) | VAF 25/211 reads (12%) | catalogued as COSV51997138; called by muse, mutect2, varscan2
- HNF1B | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as rs747360527; called by muse, mutect2
- HNRNPU | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.864); catalogued as rs773969888; called by muse, mutect2, varscan2
- INTS5 | c.1825G>C p.D609H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs1383273552, COSV57953001; called by muse, mutect2, varscan2
- ITGB4 | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs762830197, COSV52330962; called by mutect2, varscan2
- KDM5A | c.1100G>A p.G367E | Missense Mutation (SNP) | VAF 14/318 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV101238590; called by muse, mutect2
- KIR2DL4 | c.508C>T p.R170W (on ENST00000396284; = p.R131W on NM_001080770.2) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs747079301, COSV100610615; called by mutect2, varscan2
- KNDC1 | c.3805C>A p.L1269M | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as rs780836641; called by muse, varscan2
- LHX3 | c.177C>A p.S59R (on ENST00000371748 / NM_178138.6; = p.S64R on NM_014564.5) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.811); catalogued as COSV65581879; called by muse, mutect2, varscan2
- LRRN3 | c.1837G>T p.G613C | Missense Mutation (SNP) | VAF 16/299 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as COSV100072439; called by muse, mutect2
- MARVELD2 | c.1182G>A p.M394I | Missense Mutation (SNP) | VAF 8/207 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs1561294536; called by muse, mutect2
- RADX | c.2293G>A p.D765N | Missense Mutation (SNP) | VAF 26/304 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.595); catalogued as rs751214007; called by muse, mutect2
- RNF113A | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 20/328 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.511); catalogued as rs1476185152; called by muse, mutect2
- SRRT | c.198C>G p.F66L | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV61451874; called by muse, mutect2
- TSPAN19 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 8/149 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1191865318, COSV70813433; called by muse, mutect2
- VIT | c.899G>A p.G300E (on ENST00000389975 / NM_001177969.1; = p.G315E on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1043695163; called by muse, mutect2, varscan2
- ACACB | c.2880G>T p.R960S | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- ADGRV1 | c.1960T>G p.F654V | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2
- ADGRV1 | c.3360T>G p.I1120M | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.682); called by muse, varscan2
- ATP9B | c.1434G>A p.M478I | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, varscan2
- BRINP3 | c.1776C>A p.S592R | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2
- CCDC168 | c.14179G>C p.E4727Q | Missense Mutation (SNP) | VAF 9/216 reads (4%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.895); called by muse, mutect2
- CDH23 | c.8067C>G p.L2689= | Splice Region (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- CENPF | c.2263G>A p.D755N | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- CHRDL1 | c.588A>G p.A196= (on ENST00000372045; = p.A202= on NM_145234.4) | Splice Region (SNP) | VAF 27/203 reads (13%) | called by muse, mutect2, varscan2
- COL20A1 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- COPA | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 26/204 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CTNNAL1 | c.394A>T p.I132F | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.419); called by muse, mutect2
- DNMBP | c.3875C>G p.A1292G | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- DPP8 | c.293_294del p.R98Nfs*9 (on ENST00000341861 / NM_001320875.2; = p.R82Nfs*9 on NM_017743.6) | Frame Shift Del (DEL) | VAF 3/26 reads (12%) | called by mutect2, pindel
- ESR2 | c.53G>T p.C18F | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, varscan2
- FAM3A | c.128-2A>G p.X43_splice | Splice Site (SNP) | VAF 12/156 reads (8%) | called by muse, mutect2
- GABRQ | c.1651A>C p.K551Q | Missense Mutation (SNP) | VAF 7/194 reads (4%) | SIFT tolerated (0.48); PolyPhen benign (0.079); called by muse, mutect2
- GLB1L3 | c.787G>A p.V263M | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- HEPH | c.1238C>A p.S413* (on ENST00000343002; = p.S146* on NM_014799.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2, varscan2
- HERC1 | c.879G>T p.M293I | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2
- INO80E | c.16del p.D6Tfs*13 | Frame Shift Del (DEL) | VAF 28/148 reads (19%) | called by mutect2, pindel, varscan2
- ITGAX | c.3211G>T p.E1071* | Nonsense Mutation (SNP) | VAF 22/312 reads (7%) | called by muse, mutect2
- ITGAX | c.3349C>A p.L1117M | Missense Mutation (SNP) | VAF 16/187 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KEL | c.1741C>A p.H581N | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); called by muse, mutect2
- LRRTM3 | c.294C>A p.S98R | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.889); called by muse, varscan2
- MET | c.3160G>C p.D1054H | Missense Mutation (SNP) | VAF 24/344 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2
- MYH13 | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.028); called by muse, mutect2
- NACAD | c.3137C>G p.S1046C | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- NDST3 | c.2440G>C p.E814Q | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.356); called by muse, mutect2
- NDST4 | c.435G>T p.W145C | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NET1 | c.1361G>C p.G454A (on ENST00000355029 / NM_001047160.3; = p.G400A on NM_005863.5) | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NEXMIF | c.3545G>C p.S1182T | Missense Mutation (SNP) | VAF 14/201 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2
- OLFM1 | c.478G>A p.E160K (on ENST00000371793 / NM_001282611.2; = p.E142K on NM_014279.5) | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PLCB1 | c.1863G>T p.M621I | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- PLEKHS1 | c.876T>G p.D292E (on ENST00000369310 / NM_182601.1; = p.D298E on NM_024889.5) | Missense Mutation (SNP) | VAF 24/252 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.318); called by muse, mutect2
- PTH2R | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RGPD3 | c.5197C>T p.L1733F | Missense Mutation (SNP) | VAF 42/486 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- SLC19A2 | c.977C>G p.S326C | Missense Mutation (SNP) | VAF 38/302 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPATA31A6 | c.1526C>A p.A509D | Missense Mutation (SNP) | VAF 39/231 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- SRRM5 | c.1552G>C p.E518Q | Missense Mutation (SNP) | VAF 17/271 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); called by muse, mutect2
- TARBP1 | c.948G>T p.W316C | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- TEP1 | c.154C>G p.L52V | Missense Mutation (SNP) | VAF 61/223 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- USP26 | c.1315G>C p.E439Q | Missense Mutation (SNP) | VAF 18/460 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- ZNF185 | c.1678C>G p.P560A | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.122); called by muse, mutect2
- ZNF235 | c.860G>A p.G287E | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.154); called by muse, mutect2
- ZNF862 | c.1298C>G p.S433C | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.436); called by muse, mutect2
- ACSM5 | c.1608C>A p.L536= | Silent (SNP) | VAF 64/293 reads (22%) | catalogued as rs371902246; called by muse, mutect2, varscan2
- ADH7 | c.225A>C p.P75= | Silent (SNP) | VAF 13/189 reads (7%) | called by muse, mutect2
- ATG9A | c.192C>T p.I64= | Silent (SNP) | VAF 61/226 reads (27%) | catalogued as rs750805938; called by muse, mutect2, varscan2
- C17orf75 | c.318G>T p.G106= | Silent (SNP) | VAF 26/184 reads (14%) | catalogued as COSV56752204; called by muse, varscan2
- CNOT1 | c.5094C>T p.G1698= | Silent (SNP) | VAF 15/133 reads (11%) | catalogued as rs774826730; called by muse, mutect2, varscan2
- GRM6 | c.579G>T p.V193= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV51437248, COSV99179514; called by muse, mutect2, varscan2
- LONRF3 | c.651G>A p.Q217= | Silent (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2, varscan2
- MAGEB3 | c.621C>T p.L207= | Silent (SNP) | VAF 21/149 reads (14%) | catalogued as rs1368213130, COSV100854639; called by muse, mutect2, varscan2
- MYH1 | c.3957G>T p.L1319= | Silent (SNP) | VAF 9/142 reads (6%) | called by muse, mutect2
- NLGN4X | c.1068G>T p.L356= | Silent (SNP) | VAF 13/119 reads (11%) | called by muse, mutect2, varscan2
- NTRK3 | c.1632G>A p.L544= | Silent (SNP) | VAF 15/245 reads (6%) | called by muse, mutect2
- OCA2 | c.2265G>A p.L755= | Silent (SNP) | VAF 26/209 reads (12%) | called by muse, mutect2, varscan2
- PCNX3 | c.4545G>C p.L1515= | Silent (SNP) | VAF 14/107 reads (13%) | catalogued as rs1477582686, COSV63136104; called by muse, mutect2
- PDE6A | c.291C>T p.F97= | Silent (SNP) | VAF 11/224 reads (5%) | called by muse, mutect2
- PRAMEF1 | c.93G>T p.L31= | Silent (SNP) | VAF 12/148 reads (8%) | called by muse, mutect2
- SP4 | c.819C>T p.N273= | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as rs1049992973; called by muse, mutect2, varscan2
- STN1 | c.624G>A p.L208= | Silent (SNP) | VAF 26/90 reads (29%) | called by muse, mutect2, varscan2
- ATL2 | c.119-10628G>T | Intron (SNP) | VAF 25/82 reads (30%) | called by muse, mutect2, varscan2
- C12orf77 | n.334G>A | RNA (SNP) | VAF 14/122 reads (11%) | catalogued as rs375630600; called by muse, mutect2
- C1QTNF9B | c.167-420C>G | Intron (SNP) | VAF 55/226 reads (24%) | called by muse, mutect2, varscan2
- GUSBP10 | n.311C>T | RNA (SNP) | VAF 15/165 reads (9%) | called by muse, mutect2
- KIAA0586 | c.366-1380G>A | Intron (SNP) | VAF 16/103 reads (16%) | catalogued as rs897759486; called by muse, mutect2, varscan2
- LGALS1 | c.-13C>A | 5'UTR (SNP) | VAF 5/34 reads (15%) | catalogued as COSV53222137; called by muse, mutect2, varscan2
- LINC02877 | n.554A>G | RNA (SNP) | VAF 31/175 reads (18%) | called by muse, mutect2, varscan2
- LONRF3 | c.1060-2469C>A | Intron (SNP) | VAF 11/157 reads (7%) | called by muse, mutect2
- MIR518A1 | n.2C>A | RNA (SNP) | VAF 8/201 reads (4%) | called by muse, mutect2
- PSTPIP2 | c.*13C>A | 3'UTR (SNP) | VAF 17/190 reads (9%) | called by muse, mutect2
- TMEM135 | c.*7381C>T | 3'UTR (SNP) | VAF 8/202 reads (4%) | catalogued as rs1392942060; called by muse, mutect2
- WDR33 | c.626+77G>C | Intron (SNP) | VAF 26/321 reads (8%) | catalogued as COSV59253140; called by muse, mutect2
